Somatic mutation profile of tumor specimen MP2PRT-PAUGEG-TMP1-A (aliquot MP2PRT-PAUGEG-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUGEG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,886 days).
Specimen MP2PRT-PAUGEG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d437a7d4-5d7c-4fab-aec1-20bc3e1d89d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGEG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGEG-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de47da5a-3957-477a-95e7-8229c2ddb20b

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDAN1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474400715, COSV51158046; called by muse, mutect2, varscan2
- RNF113B | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 195/511 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV57435927, COSV99940453; called by muse, mutect2, varscan2
- UBA2 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 81/243 reads (33%) | catalogued as COSV55831179; called by muse, mutect2, varscan2
- ALOX15B | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 188/519 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- BRPF3 | c.662_663del p.D221Gfs*5 | Frame Shift Del (DEL) | VAF 53/260 reads (20%) | called by pindel*, varscan2
- LRWD1 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 212/539 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.35); called by muse, mutect2, varscan2
